Gene-level copy-number profile of tumor specimen TCGA-B0-4701-01A from TCGA case TCGA-B0-4701, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 66.3 years (24,232 days).
Specimen TCGA-B0-4701-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.2c57b2bc-437e-498d-a926-a1456ef1f368.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B0-4701-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5576da84-9084-400f-b674-8cd82670dd6f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,064; copy number 2: 57,613; copy number 3: 1,143.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-B0-4701-01): tumor purity 0.42, ploidy 2, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,064. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
